Somatic mutation profile of tumor specimen C3L-02348-02 (aliquot CPT0115070009) from CPTAC case C3L-02348, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.3 years (21,302 days).
Specimen C3L-02348-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b17b90d1-8c50-4c01-8cc4-c004c5038e60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02348-31 (Blood Derived Normal), aliquot CPT0115320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/843d7ca4-9483-4ee2-8b1d-628e1ed8d1b2

The open-access MAF lists 78 somatic variants for this specimen: 52 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Nonsense Mutation 5, 5'UTR 5, Frame Shift Del 3, Intron 3, 3'UTR 2, 3'Flank 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 139/702 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen possibly damaging (0.629); catalogued as rs121913494, COSV55670795, COSV55671120; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 53/223 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CSMD3 | c.4223C>A p.P1408H (on ENST00000297405 / NM_001363185.1; = p.P1304H on NM_052900.3) | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1463061612; called by muse, mutect2, varscan2
- DEAF1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 23/385 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1373112573, COSV58606109; called by muse, mutect2
- DPY19L2 | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV61046706; called by muse, mutect2, varscan2
- FAM124A | c.791G>A p.R264H (on ENST00000322475 / NM_001242312.2; = p.R300H on NM_145019.4) | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374624217; called by muse, mutect2, varscan2
- FHOD3 | c.3961T>A p.S1321T (on ENST00000359247 / NM_001281739.3; = p.S1338T on NM_025135.5) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.22); catalogued as rs895335894; called by muse, mutect2, varscan2
- FOXI2 | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV59094380; called by muse, mutect2, varscan2
- GPRC5D | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs750194630; called by muse, mutect2, varscan2
- KCNG2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.402); catalogued as rs776250759; called by muse, mutect2, varscan2
- MKNK1 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs529428152; called by muse, mutect2, varscan2
- NCAPD3 | c.525G>T p.R175S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV73258409; called by muse, mutect2, varscan2
- PRR16 | c.688G>T p.E230* (on ENST00000407149 / NM_001300783.2; = p.E207* on NM_016644.2) | Nonsense Mutation (SNP) | VAF 26/195 reads (13%) | catalogued as COSV65395265; called by muse, mutect2, varscan2
- STAT1 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs780156389; called by muse, mutect2
- TEPSIN | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs778232819; called by muse, mutect2, varscan2
- TTN | c.8377G>A p.E2793K (on ENST00000591111; = p.E2747K on NM_003319.4) | Missense Mutation (SNP) | VAF 78/425 reads (18%) | PolyPhen possibly damaging (0.894); catalogued as COSV100609527; called by muse, mutect2, varscan2
- ZSCAN31 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 38/207 reads (18%) | catalogued as rs971227763; called by muse, mutect2, varscan2
- ACLY | c.345+1G>A p.X115_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- ACSM2A | c.1096A>G p.T366A (on ENST00000219054; = p.T287A on NM_001308169.2) | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.291); called by muse, varscan2
- AKAP13 | c.6317A>T p.Q2106L (on ENST00000394518 / NM_007200.5; = p.Q2110L on NM_006738.6) | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANO1 | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- APOOL | c.572C>A p.S191* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- CCDC59 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- CEP295 | c.3284G>T p.G1095V | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CNTNAP5 | c.3254C>A p.T1085N | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL9A2 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CREBBP | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DDX24 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EML1 | c.132A>T p.R44S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- EYS | c.1113A>T p.Q371H | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- FAM110D | c.500A>C p.N167T | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- FAM149B1 | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- FAM178B | c.1444A>T p.I482F | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- FCGBP | c.10286A>C p.K3429T | Missense Mutation (SNP) | VAF 95/632 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FGD5 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYI | c.718C>A p.Q240K (on ENST00000372434 / NM_001330526.2; = p.Q215K on NM_031207.6) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ISG20 | c.36C>G p.C12W | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAP3 | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- LIN7A | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, varscan2
- LSR | c.1275_1282del p.R426Afs*5 (on ENST00000361790; = p.R407Afs*5 on NM_015925.6) | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- LZTR1 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NKTR | c.2746T>C p.S916P | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- PPP4R3A | c.785A>C p.H262P | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM14 | c.136del p.A46Rfs*66 | Frame Shift Del (DEL) | VAF 34/174 reads (20%) | called by mutect2, pindel, varscan2
- RESF1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 66/382 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- SLC4A10 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC9A3R2 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- SYCP2 | c.1180A>T p.R394W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2
- SYNE1 | c.8024G>A p.G2675D (on ENST00000367255 / NM_182961.4; = p.G2682D on NM_033071.3) | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFX | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF281 | c.195del p.P66Rfs*33 | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | called by mutect2, pindel, varscan2
- ZNF768 | c.1143C>A p.C381* | Nonsense Mutation (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- CCDC50 | c.1383G>A p.Q461= (on ENST00000392455 / NM_178335.3; = p.Q285= on NM_174908.4) | Silent (SNP) | VAF 27/399 reads (7%) | called by muse, mutect2
- DPP6 | c.300G>T p.L100= (on ENST00000377770 / NM_001364500.2; = p.L38= on NM_001936.5) | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs770515048; called by muse, mutect2, varscan2
- DYRK2 | c.555T>A p.G185= (on ENST00000344096 / NM_006482.3; = p.G112= on NM_003583.4) | Silent (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- FLG | c.11556G>A p.G3852= | Silent (SNP) | VAF 21/600 reads (4%) | called by muse, mutect2
- GPR108 | c.351C>T p.F117= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- HMCN2 | c.1101C>A p.P367= | Silent (SNP) | VAF 46/254 reads (18%) | called by muse, mutect2, varscan2
- HRH4 | c.228G>T p.T76= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as COSV56928040, COSV56929248; called by muse, mutect2, varscan2
- HSF1 | c.1326C>T p.L442= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs375849065; called by muse, mutect2, varscan2
- MEGF6 | c.1866C>G p.L622= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as rs1241651939; called by muse, mutect2, varscan2
- PACSIN2 | c.117C>T p.S39= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as rs750019106; called by muse, mutect2, varscan2
- RAB44 | c.90C>T p.G30= | Silent (SNP) | VAF 29/296 reads (10%) | catalogued as rs963178766; called by muse, mutect2, varscan2
- RNF125 | c.519C>T p.C173= | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- TMEM221 | c.138C>A p.A46= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2
- ADGRG3 | c.-17G>A | 5'UTR (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- CACNA1D | c.4924-3896dup | Intron (INS) | VAF 19/192 reads (10%) | called by mutect2, pindel
- CYP3A5 | c.-2C>T | 5'UTR (SNP) | VAF 21/185 reads (11%) | catalogued as rs775307047; called by muse, mutect2, varscan2
- ENTPD5 | chr14:73958933 G>A | 3'Flank (SNP) | VAF 78/385 reads (20%) | called by muse, mutect2, varscan2
- GABARAPL2 | c.-26G>T | 5'UTR (SNP) | VAF 22/141 reads (16%) | catalogued as rs1258742470; called by muse, mutect2, varscan2
- IGF2BP2 | c.240-23909A>G | Intron (SNP) | VAF 10/240 reads (4%) | catalogued as rs1176527510; called by muse, mutect2
- MIR325 | n.79A>T | RNA (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- PEG10 | c.-13G>A | 5'UTR (SNP) | VAF 24/105 reads (23%) | called by muse, varscan2
- PPP4R4 | c.-32C>G | 5'UTR (SNP) | VAF 7/97 reads (7%) | catalogued as COSV58556496; called by muse, mutect2
- RNGTT | c.1506+79C>G | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs1210042938; called by muse, mutect2, varscan2
- UAP1L1 | chr9:137086674 G>C | 3'Flank (SNP) | VAF 14/212 reads (7%) | catalogued as rs1376415983; called by muse, mutect2
- YME1L1 | c.*142C>G | 3'UTR (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- ZDHHC3 | c.*8741G>T | 3'UTR (SNP) | VAF 66/277 reads (24%) | called by muse, mutect2, varscan2
